Gene-level copy-number profile of tumor specimen TCGA-CA-5254-01A from TCGA case TCGA-CA-5254, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 42.2 years (15,415 days).
Specimen TCGA-CA-5254-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.14457cb4-3025-42a1-a9ce-daa82b16a7b7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CA-5254-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9714fc4a-a0dc-4805-b1ec-94e6995b8706

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 31; copy number 1: 471; copy number 2: 12,899; copy number 3: 26,671; copy number 4: 18,791; copy number 5: 363; copy number 6: 163; copy number 7: 6; copy number 8: 93; copy number 10: 183; copy number 14: 93; copy number 15: 51.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CA-5254-01A-21D-1834-01): tumor purity 0.72, ploidy 3.12, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:174,091,766–175,236,669, 16 genes: LINC02268, AC012055.1, AC012055.2, FBXO8, CEP44, AC116616.1, MIR4276, HPGD, AC096751.2, AC096751.1, GLRA3, ADAM29, AC105914.1, AC105914.2, AC022325.1, AC022325.2.
- chr4:178,116,721–179,465,305, 6 genes: RNU1-45P, AC095041.1, RNA5SP173, AC017087.1, AC018710.1, AC020551.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 426 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:59,809,269–59,811,310, 1 gene, copy number 7: AC093418.1.
- chr3:185,476,496–185,633,551, 5 genes, copy number 7 (within-gene range 4–7): TMEM41A, AC099661.1, LIPH, SENP2, AC133473.1.
- chr17:38,800,441–41,734,644, 183 genes, copy number 10 (broad region; genes not listed).
- chr17:58,755,854–63,989,422, 179 genes, copy number 8–14 (broad region; genes not listed).
- chr17:67,044,554–68,551,319, 51 genes, copy number 15 (within-gene range 3–15): CACNG1, HELZ, AC007448.3, RPL36AP48, AC007448.5, AC007448.4, RNA5SP447, AC007448.1, AC007448.2, PSMD12, PITPNC1, Y_RNA, RN7SL756P, MIR548AA2, MIR548D2, AC110921.1, AC079331.2, AC079331.1, AC079331.3, NOL11, SNORA38B, RPSAP67, RPL17P41, BPTF, AC134407.1, AC134407.2, AC134407.3, RN7SL622P, C17orf58, KPNA2, FBXO36P1, AC145343.1, LINC00674, LRRC37A16P, AC005332.6, AC005332.3, AC005332.5, SH3GL1P3, RDM1P3, AC005332.7, AC005332.2, ARHGAP27P2, AC005332.4, AMZ2, AC005332.1, ARSG, SLC16A6, AC007780.1, WIPI1, MIR635, PRKAR1A.
- chr17:69,577,251–70,135,608, 7 genes, copy number 14 (within-gene range 3–14): LINC01483, AC002545.1, LINC01497, Y_RNA, AC005208.1, LINC01028, KCNJ16.

Autosomal genes at a single copy (total copy number 1): 471. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
